Surgical pathology report (de-identified scan), TCGA case TCGA-78-7148, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-7148-01A (Primary Tumor).

HISTORY

Adenocarcinoma LU lobe on [REDACTED]
No previous therapy.

MACROSCOPIC

Four specimens received.

1: The specimen is labelled "L upper lobe" and consists of an upper lobe measuring 205 x 145 x 40 mm in the inflated state. Deep to the lateral pleura there is a firm white nodule measuring 43 mm in maximal dimension. It has a somewhat glistening mucoid cut surface. [Sections taken: bronchial resection margin and peribronchial lymph nodes, 1A; further lymph nodes, 1B; tumour and pleura, 1C-1D; tumour near to hilum, 1E; distal tumour with focal obstructive pneumonitis, 1F; apical and basal portions of lung, 1G]

2: The specimen is labelled "peribronchial lymph node" and consists of a piece of tan lymph node tissue measuring 19 x 18 x 10 mm. [Bisected and BIT]

3: The specimen is labelled "No. 5 node" and consists of a piece of fatty tissue containing a blackened lymph node and measuring 11 x 7 x 6 mm. [Bisected and BIT]

4: The specimen is labelled "No. 6 node" and consists of two pieces of blackened lymph node with attached fat. These piece each measure 15 x 11 x 6 mm and 21 x 9 x 8 mm. [Each piece bisected and all BIT]

MICROSCOPIC

1: Sections show a well-differentiated mucinous adenocarcinoma. The tumour has a predominantly bronchioloalveolar pattern but there are areas of stromal invasion. In some areas the tumour has a papillary architecture. The lesion is subpleural but no pleural invasion is identified. Lymphatic permeation is present and there is metastatic carcinoma within some of the peribronchial lymph nodes. There is no blood vessel invasion and no perineural permeation is identified. The lesion is well clear of the bronchial resection margin. The adjacent lung shows evidence of emphysema.

2: The lymph node contains metastatic mucinous adenocarcinoma.

3: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

4: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

SUMMARY

Left upper lobe lung and lymph nodes:

- 1: Well-differentiated mucinous adenocarcinoma; 43 mm in maximal dimension.
- 2: Lymphatic permeation present but no blood vessel or perineural invasion present.
- 3: No pleural invasion identified; clear of bronchial margin.
- 4: Peribronchial lymph node metastases but no involvement of No 5 and No 6 lymph nodes.
- 5: T2N1MX

Copies:

Source: NCI Genomic Data Commons file af2b2cb1-6f3d-4dd4-913a-d38f52949a2b (TCGA-78-7148.5C97D03F-3DFC-4876-AB9E-AD2F4606D62B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).